Somatic mutation profile of tumor specimen TARGET-10-PARFSF-09A (aliquot TARGET-10-PARFSF-09A-01D) from TARGET case TARGET-10-PARFSF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (919 days).
Specimen TARGET-10-PARFSF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7357d35f-1a3d-4f70-8a03-b7e4648e6d9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFSF-14A (Bone Marrow Normal), aliquot TARGET-10-PARFSF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e1b6634-0bc5-4c22-9001-697eb5142712

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 2, Nonsense Mutation 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD5 | c.5566G>A p.V1856I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as rs762621807; called by muse, varscan2
- DUSP11 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99731322; called by muse, varscan2
- GP2 | c.874C>A p.Q292K (on ENST00000381362 / NM_001007240.3; = p.Q289K on NM_001502.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1567289374, COSV56895190; called by muse, mutect2, varscan2
- KRT81 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as COSV59811246; called by mutect2, varscan2
- OR5D14 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100162038, COSV59457922; called by muse, mutect2
- ARHGAP21 | c.3609G>T p.M1203I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- C3AR1 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CIDEC | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGB4 | c.3890C>A p.T1297K | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.836); called by muse, mutect2
- KLF9 | c.648C>G p.D216E | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.3257G>T p.C1086F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MBD3L3 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MTCL1 | c.3536C>A p.A1179D (on ENST00000306329 / NM_001378206.1; = p.A860D on NM_015210.4) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NEDD4 | c.1795G>T p.A599S (on ENST00000508342 / NM_001284338.1; = p.A180S on NM_006154.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2
- NID1 | c.1487G>T p.W496L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOTCH3 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PSD4 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); called by muse, mutect2
- SLC9B1P1 | n.725G>T | Splice Region (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- SNRPN | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP9X | c.6887C>A p.S2296* | Nonsense Mutation (SNP) | VAF 168/174 reads (97%) | called by muse, mutect2, varscan2
- AC007342.3 | n.324G>A | RNA (SNP) | VAF 26/88 reads (30%) | catalogued as rs756141873; called by muse, mutect2, varscan2
- ENO3 | c.181+48C>A | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- MAML3 | c.468+18621G>T | Intron (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2
- UBBP4 | n.637C>T | RNA (SNP) | VAF 27/91 reads (30%) | catalogued as rs751170644; called by muse, mutect2, varscan2
